Somatic mutation profile of tumor specimen TCGA-66-2759-01A (aliquot TCGA-66-2759-01A-01D-1522-08) from TCGA case TCGA-66-2759, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.5 years (24,287 days).
Specimen TCGA-66-2759-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66b4ebca-20fa-400c-b641-996f9544833a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2759-11A (Solid Tissue Normal), aliquot TCGA-66-2759-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3252f77d-b5c5-4dea-b42d-a9010ca2fa3a

The open-access MAF lists 457 somatic variants for this specimen: 339 protein-altering or splice-affecting, 107 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 291, Silent 107, Nonsense Mutation 26, Frame Shift Del 8, Splice Region 7, RNA 6, Splice Site 4, Intron 4, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 43/162 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- WNT7A | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514666, CM110768, COSV53196797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2222G>T p.R741I | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs1359542599, COSV55944473, COSV55960216; called by muse, mutect2, varscan2
- ABCC12 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60917089; called by muse, mutect2, varscan2
- ACSM2A | c.1205T>G p.L402R (on ENST00000219054; = p.L323R on NM_001308169.2) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54588378; called by muse, mutect2, varscan2
- ADAM22 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55986573; called by muse, mutect2, varscan2
- ADAMTS19 | c.2699A>T p.H900L | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50782157; called by muse, mutect2, varscan2
- ADAT1 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 35/138 reads (25%) | catalogued as COSV57188025; called by muse, mutect2, varscan2
- AGBL1 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV66869429; called by muse, mutect2, varscan2
- AGTR1 | c.633T>G p.I211M | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62559696; called by muse, mutect2, varscan2
- AHI1 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV55633732; called by muse, mutect2, varscan2
- ALDOB | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66398433, COSV99058870; called by muse, mutect2, varscan2
- ALPK2 | c.149A>C p.Q50P | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV64495856; called by muse, mutect2, varscan2
- AMY2B | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 131/707 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63716611; called by muse, mutect2, varscan2
- ANK2 | c.10046C>T p.P3349L | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100003248, COSV52180948; called by muse, mutect2, varscan2
- ANO5 | c.42G>T p.G14= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61089018; called by mutect2, varscan2
- ANP32B | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 68/187 reads (36%) | catalogued as COSV59587524; called by muse, mutect2, varscan2
- APBB1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54979645; called by muse, mutect2, varscan2
- ARMC1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV52534580; called by muse, mutect2, varscan2
- ASPM | c.8094C>G p.F2698L | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV54136027; called by muse, mutect2, varscan2
- ATAT1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs760636161, COSV53315730; called by muse, mutect2, varscan2
- ATF7IP | c.3145A>C p.T1049P | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); catalogued as rs779593459, COSV53775695; called by muse, mutect2, varscan2
- ATG13 | c.1076G>T p.R359L (on ENST00000359513 / NM_001346321.1; = p.R322L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV56321446; called by muse, mutect2, varscan2
- ATP10A | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV63521854; called by muse, mutect2, varscan2
- ATP6V1A | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56363875; called by muse, mutect2, varscan2
- ATRNL1 | c.1888G>C p.G630R | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV61796035, COSV61813253; called by muse, mutect2, varscan2
- ATXN2 | c.2692G>T p.D898Y (on ENST00000550104; = p.D738Y on NM_002973.4) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66485449; called by muse, mutect2, varscan2
- B3GALT1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs746868901, COSV59908017; called by muse, mutect2, varscan2
- BCHE | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV52258770, COSV52260684, COSV52263960; called by muse, mutect2, varscan2
- BIRC6 | c.13588G>T p.A4530S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV70204096; called by muse, mutect2, varscan2
- BRSK2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771787614, COSV57547407; called by muse, mutect2, varscan2
- BTNL9 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59798518; called by muse, mutect2, varscan2
- C1D | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs752414784, COSV63413769; called by muse, mutect2
- C6 | c.2242G>C p.G748R | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV54715978, COSV99666481; called by muse, mutect2, varscan2
- CALCR | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426673237, COSV64009835, COSV64011006; called by muse, mutect2, varscan2
- CCDC18 | c.3157G>A p.E1053K (on ENST00000343253 / NM_001306076.1; = p.E1054K on NM_206886.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV58146546; called by muse, mutect2, varscan2
- CCNA2 | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52658798; called by muse, mutect2, varscan2
- CCNJL | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV57446322; called by muse, mutect2, varscan2
- CDH1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs864622184, COSV55729855, COSV55738645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52570402, COSV52592855; called by muse, mutect2, varscan2
- CDH2 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 60/452 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV52292173; called by muse, mutect2, varscan2
- CENPW | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 89/157 reads (57%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV64177153; called by muse, mutect2, varscan2
- CEP89 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as COSV59866795; called by muse, mutect2, varscan2
- CES5A | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51869424; called by muse, mutect2, varscan2
- CFAP97 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71712876; called by muse, mutect2, varscan2
- CFL2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs779077709, COSV53311167; called by muse, mutect2, varscan2
- CHRNA9 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1342521367, COSV59573400; called by muse, mutect2, varscan2
- CNKSR2 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV54263685; called by muse, mutect2, varscan2
- CNTNAP2 | c.1519A>T p.N507Y | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV62237800; called by muse, varscan2
- CNTNAP4 | c.1681G>C p.G561R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100271916, COSV56695578; called by muse, varscan2
- CNTNAP4 | c.2695A>T p.T899S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV56695589; called by muse, mutect2, varscan2
- COL11A1 | c.4304G>T p.G1435V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62188973, COSV62192654; called by muse, mutect2, varscan2
- COL1A1 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56806219; called by muse, mutect2, varscan2
- COL4A1 | c.1700C>A p.P567Q | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV65427806, COSV65430121; called by muse, mutect2, varscan2
- COL8A1 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53740215; called by muse, mutect2, varscan2
- CPB2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51676650; called by muse, mutect2
- CROT | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV58976276; called by muse, mutect2, varscan2
- CRY1 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV50488434; called by muse, mutect2, varscan2
- CYP2C9 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV53251604; called by muse, mutect2, varscan2
- DBNDD2 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV61919260; called by muse, mutect2, varscan2
- DECR1 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV55170110; called by muse, mutect2, varscan2
- DENND5A | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60236938; called by muse, varscan2
- DHRSX | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58137729; called by muse, mutect2, varscan2
- DHX32 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs370623553; called by muse, mutect2, varscan2
- DMBX1 | c.36C>A p.H12Q | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63602462; called by muse, mutect2, varscan2
- DMD | c.7978C>T p.H2660Y | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs757616080, COSV58940372; called by muse, mutect2, varscan2
- DNAH8 | c.6313C>T p.P2105S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV59471853; called by muse, mutect2, varscan2
- DPP8 | c.1631A>G p.K544R (on ENST00000341861 / NM_001320875.2; = p.K528R on NM_017743.6) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.123); catalogued as COSV55682101; called by muse, mutect2, varscan2
- DSC1 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 160/375 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.287); catalogued as COSV57149875; called by muse, mutect2, varscan2
- EBF1 | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58190481; called by muse, mutect2, varscan2
- EDEM3 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436390075, COSV58927026; called by muse, mutect2, varscan2
- EEF2K | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.862); catalogued as COSV53785747; called by muse, varscan2
- EIF5 | c.153G>T p.T51= | Splice Region (SNP) | VAF 31/53 reads (58%) | catalogued as COSV53686465; called by muse, mutect2, varscan2
- ENOX2 | c.445G>T p.E149* (on ENST00000338144 / NM_001382520.1; = p.E120* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 151/215 reads (70%) | catalogued as COSV100584325, COSV57656535; called by muse, mutect2, varscan2
- ENPEP | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.068); catalogued as COSV54455831; called by muse, mutect2, varscan2
- EPG5 | c.7030G>T p.G2344* | Nonsense Mutation (SNP) | VAF 49/166 reads (30%) | catalogued as COSV56354478; called by muse, mutect2, varscan2
- EPHB2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV65865371; called by muse, mutect2, varscan2
- ERICH3 | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs759558131, COSV58606884, COSV58611028; called by muse, mutect2, varscan2
- ERICH3 | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1417236438, COSV58614924; called by muse, mutect2, varscan2
- FAM90A1 | c.132C>A p.C44* | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | catalogued as COSV56714157; called by muse, mutect2, varscan2
- FASTKD3 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52946103; called by muse, mutect2, varscan2
- FAT2 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV55826977; called by muse, mutect2, varscan2
- FBXO9 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55056824; called by muse, mutect2, varscan2
- FER1L6 | c.198-1G>T p.X66_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101205590, COSV67552110; called by muse, mutect2, varscan2
- FGF14 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1228022005, COSV65953827; called by muse, mutect2, varscan2
- FLG2 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 449/833 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs763201806, COSV66171739; called by muse, mutect2, varscan2
- FLT4 | c.3214G>A p.G1072S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56104421; called by muse, mutect2
- FLT4 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56118512; called by muse, mutect2, varscan2
- FXR1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 76/457 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV59765588; called by mutect2, varscan2
- GABRB2 | c.528G>T p.L176F | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50933305; called by muse, mutect2
- GALNT13 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV101222170, COSV67233749; called by muse, mutect2, varscan2
- GALNT17 | c.1758C>A p.C586* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | catalogued as COSV61183053; called by muse, mutect2, varscan2
- GANC | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 36/145 reads (25%) | PolyPhen benign (0.014); catalogued as COSV58811058; called by muse, mutect2, varscan2
- GAS6 | c.552C>G p.S184R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV59854646; called by muse, mutect2, varscan2
- GFRAL | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61234160; called by muse, mutect2, varscan2
- GIMAP6 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV61034431; called by muse, mutect2
- GLIPR1L1 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1241605702, COSV56883363; called by muse, mutect2, varscan2
- GOLT1B | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554025; called by muse, mutect2, varscan2
- GP5 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.386); catalogued as COSV55468440, COSV99757188; called by muse, varscan2
- GPR87 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs531293531, COSV53464157; called by muse, mutect2
- GRIA3 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52075945; called by muse, mutect2, varscan2
- GRIA3 | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 164/247 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52075977; called by muse, mutect2, varscan2
- GRIA3 | c.1901G>C p.G634A | Missense Mutation (SNP) | VAF 146/251 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52076006; called by muse, mutect2, varscan2
- GRID1 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV60046448; called by muse, mutect2, varscan2
- GRIK2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59760879; called by muse, mutect2, varscan2
- GRPR | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 135/223 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.204); catalogued as COSV66670076; called by muse, mutect2, varscan2
- H2AC17 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV58153657; called by muse, mutect2, varscan2
- H2BC17 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV100377708, COSV58152797; called by muse, mutect2, varscan2
- HDAC9 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67771105; called by muse, mutect2, varscan2
- HECW2 | c.2185G>T p.D729Y | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.259); catalogued as COSV53664965, COSV53670518; called by muse, mutect2, varscan2
- HGF | c.1245G>A p.W415* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV55954800; called by muse, mutect2, varscan2
- HHIPL2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147794680; called by muse, varscan2
- HNRNPC | c.790G>T p.G264W (on ENST00000420743; = p.G251W on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60146733; called by muse, mutect2, varscan2
- HOXD8 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 47/238 reads (20%) | catalogued as COSV57486540; called by muse, mutect2, varscan2
- HRH4 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 78/161 reads (48%) | catalogued as COSV56927364, COSV56929370; called by muse, mutect2, varscan2
- HROB | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372363245, COSV55370390; called by muse, mutect2, varscan2
- HUS1B | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100032947, COSV57870288; called by muse, mutect2, varscan2
- IBSP | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV56896863; called by muse, mutect2, varscan2
- IGSF8 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58758944; called by muse, mutect2, varscan2
- IL1RL1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 223/452 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119459; called by muse, mutect2, varscan2
- IL23R | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.178); catalogued as COSV61375756; called by muse, mutect2, varscan2
- INO80 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV62741579; called by muse, mutect2, varscan2
- ITGA2 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56865073; called by muse, mutect2, varscan2
- ITGA5 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53220005; called by muse, mutect2, varscan2
- JAGN1 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as COSV57062734; called by muse, mutect2, varscan2
- KCNH7 | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59785044, COSV59809040; called by muse, mutect2, varscan2
- KCNJ3 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV54542210; called by muse, mutect2, varscan2
- KCNQ3 | c.2614A>C p.I872L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV66478967; called by muse, mutect2, varscan2
- KCNQ3 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66478975; called by muse, mutect2, varscan2
- KCTD8 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 148/274 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV63588502, COSV63594237; called by muse, mutect2, varscan2
- KDM4D | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58635901; called by muse, mutect2, varscan2
- KIF2B | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV52134256; called by muse, mutect2, varscan2
- KIF9 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 134/279 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55522654; called by muse, mutect2, varscan2
- KLF9 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV65808040; called by muse, mutect2, varscan2
- KLHL34 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65280104; called by muse, mutect2, varscan2
- KLK3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58102218; called by muse, mutect2, varscan2
- KMT2A | c.11167C>G p.L3723V | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.047); catalogued as COSV63290739, COSV63293807; called by muse, mutect2, varscan2
- KRT16 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV56969254; called by muse, mutect2, varscan2
- KYNU | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51589513; called by muse, mutect2, varscan2
- LEPR | c.3058T>A p.L1020M | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as COSV62750776; called by muse, mutect2, varscan2
- LIFR | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773256377, COSV54688433, COSV54693340; called by muse, mutect2, varscan2
- LNPK | c.1060T>G p.L354V | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55825779; called by muse, varscan2
- LONP2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53524925; called by muse, mutect2, varscan2
- LPP | c.1541T>G p.F514C | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756943851, COSV57108772; called by muse, mutect2, varscan2
- LRP2 | c.11809A>G p.N3937D | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV55568165; called by muse, mutect2, varscan2
- LRRFIP1 | c.517A>T p.K173* (on ENST00000392000 / NM_001137552.2; = p.K149* on NM_004735.4) | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | catalogued as COSV55255207; called by muse, mutect2, varscan2
- LRRTM1 | c.1041C>A p.Y347* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV54445311, COSV54447246; called by muse, mutect2, varscan2
- LRRTM1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs762370564, COSV54440772; called by muse, mutect2, varscan2
- M1AP | c.1142C>G p.A381G | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV51847409; called by muse, mutect2, varscan2
- MCCC1 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV55611065; called by muse, mutect2, varscan2
- MCF2L2 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV61054597, COSV61059344; called by muse, mutect2, varscan2
- MED18 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 105/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65790900, COSV65791025; called by muse, mutect2, varscan2
- MKRN1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV55438117; called by muse, mutect2, varscan2
- MME | c.1447C>G p.P483A | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV64706460, COSV64709533; called by muse, mutect2
- MPP7 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV61735993, COSV61736578; called by muse, mutect2, varscan2
- MSANTD2 | c.1352G>T p.R451L (on ENST00000374979 / NM_001308027.2; = p.R399L on NM_024631.4) | Missense Mutation (SNP) | VAF 221/426 reads (52%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV53450473; called by muse, mutect2, varscan2
- MTERF4 | c.883A>T p.R295* | Nonsense Mutation (SNP) | VAF 65/230 reads (28%) | catalogued as COSV54090559; called by muse, mutect2, varscan2
- MTHFR | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56742411; called by muse, mutect2, varscan2
- MUC16 | c.40619A>T p.K13540M | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66695561; called by muse, mutect2, varscan2
- MYH2 | c.5371A>G p.N1791D | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55445671; called by muse, mutect2, varscan2
- MYH4 | c.5344C>T p.H1782Y | Missense Mutation (SNP) | VAF 118/224 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55124004; called by muse, mutect2, varscan2
- NAALAD2 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 35/310 reads (11%) | catalogued as COSV58959808, COSV58964692; called by muse, mutect2, varscan2
- NAF1 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV56803477, COSV56805608; called by muse, mutect2, varscan2
- NALCN | c.2316C>G p.N772K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV51956835; called by muse, mutect2, varscan2
- NALCN | c.1574T>C p.L525S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51956844; called by muse, mutect2, varscan2
- NCOA6 | c.5588G>T p.G1863V | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.127); catalogued as COSV62866749; called by muse, mutect2, varscan2
- NDC1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV52338050; called by muse, mutect2, varscan2
- NDST4 | c.2578C>A p.L860M | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV52132260; called by muse, mutect2, varscan2
- NEK5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62881389; called by muse, mutect2, varscan2
- NLGN4Y | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV59298918; called by muse, mutect2, varscan2
- NME8 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV52254274; called by muse, mutect2, varscan2
- NOD2 | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV56053885; called by muse, mutect2, varscan2
- NOTCH1 | c.6632C>G p.S2211* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV53032909; called by muse, mutect2, varscan2
- NPAP1 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.791); catalogued as COSV61510142, COSV61512194; called by muse, mutect2, varscan2
- NPBWR2 | c.592G>T p.G198W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV63900493; called by muse, mutect2, varscan2
- NRK | c.2570C>G p.P857R | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV54603676; called by muse, mutect2, varscan2
- NSD3 | c.3928C>T p.R1310* | Nonsense Mutation (SNP) | VAF 21/375 reads (6%) | catalogued as COSV104395134, COSV57666971; called by muse, mutect2
- NT5C2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV58418569; called by muse, mutect2, varscan2
- NXPE3 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV56291652; called by muse, mutect2
- NXPE4 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 219/418 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV64944250; called by muse, mutect2, varscan2
- OAS3 | c.805T>A p.W269R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57448236; called by muse, mutect2, varscan2
- OR2D2 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV55057988; called by muse, mutect2, varscan2
- OR2G6 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58574384; called by muse, mutect2
- OR4C6 | c.171G>C p.M57I | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV58602424, COSV58605756; called by muse, mutect2, varscan2
- OR52J3 | c.764del p.P255Lfs*28 | Frame Shift Del (DEL) | VAF 50/251 reads (20%) | catalogued as COSV66746680, COSV66747476; called by mutect2, pindel, varscan2
- OR5D18 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100450843, COSV61738281; called by muse, mutect2, varscan2
- OR5H14 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 166/969 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101454215, COSV71194398; called by muse, mutect2, varscan2
- OR5M11 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73141656, COSV73141975; called by muse, mutect2, varscan2
- OR5T2 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1187096923, COSV57590534, COSV57591510; called by muse, mutect2, varscan2
- OR5W2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV60617857; called by muse, mutect2, varscan2
- OR6Y1 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 128/207 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV56930984; called by muse, mutect2, varscan2
- OR8B4 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1402100050, COSV62070339; called by muse, mutect2, varscan2
- OR8D4 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV58431170; called by muse, mutect2, varscan2
- OR8D4 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754468576, COSV58431181, COSV58431755; called by muse, varscan2
- P4HA2 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as COSV51329915; called by muse, mutect2
- PAK5 | c.1664C>A p.A555D | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62035027; called by muse, mutect2, varscan2
- PANX3 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52513441; called by muse, mutect2
- PAPSS2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs755679218, COSV63264694; called by muse, mutect2, varscan2
- PARPBP | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs750737952, COSV59675851; called by muse, mutect2, varscan2
- PC | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs758589916, COSV58993727; called by muse, mutect2, varscan2
- PCCA | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV66197163, COSV66200004; called by muse, mutect2, varscan2
- PCDH15 | c.2156C>A p.P719H | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV57360844, COSV57371559; called by muse, mutect2, varscan2
- PCDHB12 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs532396499, COSV53398691, COSV99507128; called by muse, mutect2, varscan2
- PCDHGA3 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV54007596; called by muse, mutect2
- PDS5A | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57829508; called by muse, mutect2
- PDZD4 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 25/40 reads (63%) | catalogued as rs1557077167, COSV51246866, COSV51249698; called by muse, mutect2, varscan2
- PHF20L1 | c.2639G>C p.G880A | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55196627; called by muse, mutect2, varscan2
- PIGN | c.2000T>C p.V667A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs747013434, COSV62951233; called by muse, mutect2, varscan2
- PIKFYVE | c.3521A>G p.K1174R | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV52237869, COSV52247032; called by muse, mutect2, varscan2
- PKHD1L1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs866893811, COSV65750112; called by muse, mutect2, varscan2
- PLCH1 | c.3628G>A p.A1210T (on ENST00000340059 / NM_001130960.2; = p.A1202T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs887061354, COSV58207488; called by muse, mutect2, varscan2
- PNLIPRP3 | c.685+2T>A p.X229_splice | Splice Site (SNP) | VAF 57/209 reads (27%) | catalogued as COSV65049315; called by muse, mutect2, varscan2
- PNPLA4 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV66854406; called by muse, mutect2, varscan2
- PORCN | c.170T>A p.V57E | Missense Mutation (SNP) | VAF 98/127 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV58226974; called by muse, mutect2, varscan2
- POTEH | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV58885822; called by muse, mutect2, varscan2
- POU4F3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1449371669, COSV57944627; called by muse, mutect2, varscan2
- PPCS | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.071); catalogued as COSV65333844; called by muse, mutect2, varscan2
- PPIL6 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 442/573 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57806619; called by muse, mutect2, varscan2
- PPP4R1 | c.2221C>G p.L741V (on ENST00000400556 / NM_001042388.3; = p.L724V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53283877; called by muse, mutect2, varscan2
- PPP4R4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 91/165 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV58557239; called by muse, mutect2, varscan2
- PTGDR | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.198); catalogued as COSV60094767; called by muse, mutect2, varscan2
- PTGS2 | c.1406-1G>C p.X469_splice | Splice Site (SNP) | VAF 110/162 reads (68%) | catalogued as COSV100821735; called by muse, mutect2, varscan2
- R3HDML | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV53837362; called by muse, mutect2, varscan2
- RAG2 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as CM114604, COSV57559138; called by muse, mutect2, varscan2
- RASD2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368099253; called by muse, mutect2, varscan2
- RBM11 | c.155T>C p.F52S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68748297; called by muse, mutect2, varscan2
- RBM8A | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV57162852; called by muse, mutect2, varscan2
- RCBTB1 | c.1443A>C p.R481S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV51636300; called by muse, mutect2, varscan2
- REC114 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV58524193; called by muse, mutect2, varscan2
- REC8 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 190/452 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61017928; called by muse, mutect2, varscan2
- REG1B | c.186C>A p.L62= | Splice Region (SNP) | VAF 28/152 reads (18%) | catalogued as COSV59304209, COSV59307286; called by muse, mutect2, varscan2
- RFPL3 | c.460C>T p.Q154* (on ENST00000249007 / NM_001098535.1; = p.Q125* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 49/174 reads (28%) | catalogued as COSV50751875; called by muse, mutect2, varscan2
- RFX6 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as COSV60585131; called by muse, mutect2, varscan2
- RIMS2 | c.521A>C p.E174A | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.824); catalogued as COSV68113280; called by muse, mutect2, varscan2
- RLF | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65652815; called by muse, varscan2
- RNASE3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.264); catalogued as rs1372547752, COSV58959761, COSV58959881; called by muse, mutect2, varscan2
- RNF148 | c.399A>T p.Q133H | Missense Mutation (SNP) | VAF 233/621 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV57379856; called by muse, mutect2, varscan2
- RNF186 | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV64296909; called by muse, mutect2, varscan2
- RP1 | c.2967G>T p.E989D | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55123921; called by muse, mutect2, varscan2
- RPS4Y2 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56488806; called by muse, mutect2, varscan2
- RTL10 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60736199; called by muse, mutect2, varscan2
- RTP2 | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 159/824 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64079348; called by muse, mutect2, varscan2
- RXFP1 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV57054678; called by muse, mutect2, varscan2
- RYR2 | c.6022G>T p.G2008* | Nonsense Mutation (SNP) | VAF 75/119 reads (63%) | catalogued as COSV63705838, COSV63724133; called by muse, mutect2, varscan2
- RYR3 | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs575120914, COSV101212122, COSV66777575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.4474G>C p.E1492Q | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV66535403, COSV66545358; called by muse, mutect2, varscan2
- SAMD12 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59055123; called by muse, mutect2
- SBSPON | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52077584; called by muse, mutect2, varscan2
- SCNN1B | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56308784; called by muse, mutect2, varscan2
- SDK1 | c.3055C>T p.L1019F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs759882865, COSV67360341, COSV67383912; called by mutect2, varscan2
- SEMA3G | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51597681; called by muse, mutect2
- SESN1 | c.496G>A p.E166K (on ENST00000356644 / NM_001199933.1; = p.E225K on NM_014454.3) | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1032022376, COSV57421660; called by muse, mutect2, varscan2
- SIM1 | c.1740C>A p.N580K | Missense Mutation (SNP) | VAF 103/194 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV53495363; called by muse, varscan2
- SLC19A2 | c.1214C>A p.T405K | Missense Mutation (SNP) | VAF 86/133 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52548667; called by muse, mutect2, varscan2
- SLIT2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56589359; called by muse, mutect2, varscan2
- SLITRK3 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53852188; called by muse, mutect2
- SLITRK3 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs894110841, COSV53852200, COSV99072036; called by muse, mutect2
- SNPH | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV60590559; called by muse, mutect2
- SOCS3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV58271176; called by muse, mutect2, varscan2
- SORCS1 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53839738; called by muse, mutect2, varscan2
- SPIC | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV54692238, COSV54692405; called by muse, mutect2, varscan2
- STAB2 | c.2442C>A p.C814* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV66344717; called by muse, mutect2, varscan2
- STARD6 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV57143231; called by muse, mutect2, varscan2
- STK31 | c.203T>A p.V68D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63458646; called by muse, mutect2, varscan2
- STPG3 | c.428A>C p.Q143P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs770341530, COSV58026103; called by muse, mutect2, varscan2
- SWI5 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV60792878; called by muse, mutect2, varscan2
- TAX1BP1 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs775012539, COSV55295936; called by muse, mutect2, varscan2
- TENT5D | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100382689, COSV57638597; called by muse, mutect2, varscan2
- TEX55 | c.466A>G p.R156G | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.37); catalogued as COSV55212475; called by muse, mutect2, varscan2
- TGM7 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV71773051; called by muse, mutect2, varscan2
- THAP12 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as COSV52612210; called by muse, mutect2
- TINAGL1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 71/185 reads (38%) | catalogued as rs1436224085, COSV54699748; called by muse, mutect2, varscan2
- TLL2 | c.2952G>A p.M984I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63574933; called by muse, mutect2, varscan2
- TLN2 | c.2634G>C p.K878N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60894021; called by muse, mutect2, varscan2
- TMC1 | c.1698T>C p.P566= | Splice Region (SNP) | VAF 77/196 reads (39%) | catalogued as COSV52782851; called by muse, mutect2, varscan2
- TNK2 | c.1164C>T p.A388= | Splice Region (SNP) | VAF 131/514 reads (25%) | catalogued as COSV57374264; called by muse, mutect2, varscan2
- TNKS2 | c.3096G>T p.G1032= | Splice Region (SNP) | VAF 35/156 reads (22%) | catalogued as COSV65416526; called by muse, varscan2
- TNXB | c.9166G>T p.E3056* (on ENST00000647633; = p.E2809* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV64477366, COSV64486489, COSV64487656; called by muse, mutect2, varscan2
- TPO | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755919271, COSV61108700; called by muse, mutect2, varscan2
- TRIM32 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs773872830, COSV57765458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM37 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1205021212, COSV51887531; called by muse, mutect2, varscan2
- TRIM51 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV55269714; called by muse, mutect2, varscan2
- TRPM6 | c.4476G>C p.K1492N | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100667093, COSV62519814; called by muse, mutect2, varscan2
- TSPAN11 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs774396624, COSV53820715; called by muse, mutect2, varscan2
- TSPAN9 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1435673633, COSV50727004; called by muse, mutect2, varscan2
- TTC14 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 26/1025 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV56013645; called by muse, mutect2
- TTC17 | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs750635072, COSV50015419; called by muse, mutect2, varscan2
- TTN | c.14209T>C p.C4737R (on ENST00000591111; = p.C3810R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/288 reads (44%) | PolyPhen probably damaging (0.998); catalogued as COSV60200307, COSV60265091; called by muse, mutect2, varscan2
- TTN | c.8630T>G p.L2877R (on ENST00000591111; = p.L2831R on NM_003319.4) | Missense Mutation (SNP) | VAF 120/283 reads (42%) | PolyPhen probably damaging (0.97); catalogued as COSV60265104; called by muse, mutect2, varscan2
- UBE2R2 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 140/217 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54292068; called by muse, mutect2, varscan2
- UBQLN3 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV61165187; called by muse, mutect2, varscan2
- UGT3A1 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV57101689; called by muse, mutect2, varscan2
- UNC79 | c.5045C>A p.A1682D (on ENST00000393151 / NM_001346218.2; = p.A1505D on NM_020818.5) | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56404493; called by muse, mutect2, varscan2
- URGCP | c.659C>T p.S220L (on ENST00000453200 / NM_001077663.3; = p.S211L on NM_017920.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.349); catalogued as rs776969467, COSV56250145, COSV56251401; called by muse, mutect2, varscan2
- USH2A | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.237); catalogued as COSV56416906; called by muse, mutect2, varscan2
- USP28 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 133/840 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV50179086, COSV99134399; called by muse, mutect2, varscan2
- VPS50 | c.2208G>A p.L736= | Splice Region (SNP) | VAF 25/165 reads (15%) | catalogued as COSV100004694, COSV59921889; called by muse, mutect2, varscan2
- VPS50 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.988); catalogued as COSV59921893; called by muse, mutect2, varscan2
- VSTM4 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53679018; called by muse, mutect2, varscan2
- VWA5A | c.1832C>A p.P611Q | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV64414038; called by muse, mutect2, varscan2
- WDFY3 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 72/177 reads (41%) | catalogued as COSV55710905; called by muse, mutect2, varscan2
- WDR35 | c.2802A>G p.I934M (on ENST00000345530 / NM_001006657.2; = p.I923M on NM_020779.4) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV55605828; called by muse, mutect2, varscan2
- WDR49 | c.1119G>T p.M373I (on ENST00000308378 / NM_001366158.1; = p.M714I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV57715328; called by muse, mutect2, varscan2
- WFIKKN2 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV60959866; called by muse, mutect2, varscan2
- WNK1 | c.3601G>C p.E1201Q (on ENST00000315939 / NM_018979.4; = p.E954Q on NM_014823.3) | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60042553; called by muse, mutect2, varscan2
- WNT2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV55412973; called by muse, mutect2, varscan2
- XIRP2 | c.7519T>G p.C2507G (on ENST00000628543; = p.C2682G on NM_152381.6) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV54725554; called by muse, mutect2, varscan2
- ZC3H12A | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV66104452; called by muse, mutect2, varscan2
- ZDHHC17 | c.1091T>C p.L364S | Missense Mutation (SNP) | VAF 115/545 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58353598; called by muse, mutect2, varscan2
- ZFHX3 | c.10360G>T p.D3454Y | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs770453754, COSV51709324, COSV51730529; called by muse, mutect2, varscan2
- ZFHX4 | c.4886G>T p.S1629I | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV51487287; called by muse, mutect2, varscan2
- ZFR | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV54053334, COSV54056731; called by muse, mutect2, varscan2
- ZIC1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51556780; called by muse, mutect2, varscan2
- ZIC4 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV67173534; called by muse, mutect2, varscan2
- ZKSCAN2 | c.947T>A p.V316D | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV60158282; called by muse, mutect2, varscan2
- ZNF146 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 64/306 reads (21%) | catalogued as COSV61932457; called by muse, mutect2, varscan2
- ZNF205 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV54622469; called by muse, varscan2
- ZNF23 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV61841538; called by muse, mutect2, varscan2
- ZNF236 | c.2363A>T p.Q788L | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV53494900; called by muse, mutect2, varscan2
- ZNF462 | c.343C>A p.R115S | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52948255; called by muse, mutect2, varscan2
- ZNF521 | c.3419G>T p.C1140F | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64130601; called by muse, mutect2, varscan2
- ZNF804A | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56465187; called by muse, mutect2, varscan2
- ZNF91 | c.2879A>G p.H960R | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56090438; called by muse, mutect2, varscan2
- ZNF91 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV56090463; called by muse, mutect2, varscan2
- ZNF99 | c.107A>T p.N36I | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101233676, COSV68056378; called by muse, mutect2
- ZSWIM2 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54578222; called by muse, mutect2, varscan2
- ABCC1 | c.2153_2162del p.Q718Lfs*20 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | called by mutect2, pindel
- ADGRG6 | c.3381_3383del p.Q1127del | In Frame Del (DEL) | VAF 72/140 reads (51%) | called by pindel, varscan2
- FKBP15 | c.3398del p.G1133Vfs*45 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV3-15 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MOB1A | c.442del p.A148Qfs*5 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- PPHLN1 | c.1115_1116insA p.A373Cfs*49 | Frame Shift Ins (INS) | VAF 77/234 reads (33%) | called by mutect2, pindel, varscan2
- PTPN4 | c.1903del p.D635Mfs*9 | Frame Shift Del (DEL) | VAF 21/151 reads (14%) | called by mutect2, pindel, varscan2
- SALL1 | c.261del p.S88Afs*11 | Frame Shift Del (DEL) | VAF 43/180 reads (24%) | called by mutect2, pindel, varscan2
- USP19 | c.1558del p.E520Nfs*21 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- USP9X | c.5685dup p.R1896Sfs*4 | Frame Shift Ins (INS) | VAF 62/119 reads (52%) | called by mutect2, pindel, varscan2
- ZNF598 | c.1285del p.V429Cfs*88 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- AADACL3 | c.888G>A p.E296= | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as COSV60200080; called by muse, mutect2, varscan2
- ABCA4 | c.6420G>T p.L2140= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV64676587; called by muse, mutect2, varscan2
- ANKRD30A | c.3099A>G p.Q1033= (on ENST00000611781; = p.Q977= on NM_052997.2) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV64617745; called by muse, mutect2, varscan2
- ANO7 | c.33C>G p.L11= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV51477140, COSV99239303; called by muse, mutect2, varscan2
- ATP10A | c.3258C>A p.A1086= | Silent (SNP) | VAF 91/234 reads (39%) | catalogued as COSV63521849; called by muse, varscan2
- ATP1A2 | c.354C>T p.A118= | Silent (SNP) | VAF 235/358 reads (66%) | catalogued as rs765171580, COSV63405377; ClinVar: likely benign; called by muse, mutect2, varscan2
- C2orf78 | c.2080C>T p.L694= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV68518880; called by muse, mutect2, varscan2
- C7orf57 | c.333G>A p.P111= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs758724934, COSV62363759; called by muse, mutect2
- CDH17 | c.444C>T p.V148= | Silent (SNP) | VAF 55/249 reads (22%) | catalogued as COSV50336697; called by muse, mutect2, varscan2
- CDH22 | c.336C>A p.I112= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs766868600, COSV64837425, COSV64839145; called by muse, mutect2, varscan2
- CHRND | c.42G>A p.L14= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs746207666, COSV51327444; called by muse, mutect2
- CNTN4 | c.2835A>G p.Q945= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1450816141, COSV61878620; called by muse, mutect2, varscan2
- COL7A1 | c.8292G>A p.E2764= | Silent (SNP) | VAF 111/228 reads (49%) | catalogued as COSV56477061; called by muse, mutect2, varscan2
- CSMD3 | c.7957C>A p.R2653= (on ENST00000297405 / NM_001363185.1; = p.R2549= on NM_052900.3) | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV52140719, COSV52280497; called by muse, mutect2, varscan2
- CTSE | c.1047C>T p.F349= (on ENST00000360218; = p.F344= on NM_001910.4) | Silent (SNP) | VAF 356/534 reads (67%) | catalogued as rs782007406, COSV63061414; called by muse, mutect2, varscan2
- DAPP1 | c.429G>C p.R143= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV56453059; called by muse, mutect2, varscan2
- DDX43 | c.12C>T p.H4= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs768641284, COSV64837693; called by muse, mutect2, varscan2
- DIDO1 | c.1791G>A p.R597= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs140512956; called by muse, varscan2
- DNAH8 | c.11370G>A p.L3790= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as COSV59471871; called by muse, mutect2, varscan2
- ECI2 | c.304C>T p.L102= (on ENST00000380118 / NM_206836.3; = p.L72= on NM_006117.2) | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as COSV60987419; called by muse, mutect2, varscan2
- EEF1B2 | c.483C>T p.C161= | Silent (SNP) | VAF 19/335 reads (6%) | catalogued as rs2359156, COSV51912616; called by muse, mutect2
- FANCE | c.330G>T p.P110= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV57690825; called by muse, mutect2, varscan2
- FCGBP | c.735G>A p.T245= | Silent (SNP) | VAF 72/513 reads (14%) | catalogued as rs142265008; called by muse, mutect2, varscan2
- FETUB | c.75C>A p.A25= | Silent (SNP) | VAF 228/960 reads (24%) | catalogued as COSV54006416, COSV54006868; called by muse, mutect2, varscan2
- FRMD4B | c.39G>T p.L13= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV68332608; called by muse, varscan2
- FZD7 | c.726G>T p.L242= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV53811219; called by muse, mutect2, varscan2
- GALNT1 | c.1191G>A p.S397= | Silent (SNP) | VAF 52/443 reads (12%) | catalogued as rs370655972, COSV99322577; called by muse, mutect2, varscan2
- GLIPR1L2 | c.258G>A p.R86= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV57555423; called by muse, mutect2, varscan2
- GMPR | c.714T>C p.F238= | Silent (SNP) | VAF 250/604 reads (41%) | catalogued as COSV52474823; called by muse, varscan2
- GOLGA6L22 | c.399T>A p.S133= | Silent (SNP) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- GP5 | c.579G>A p.Q193= | Silent (SNP) | VAF 60/416 reads (14%) | catalogued as rs200544767, COSV55468434; called by muse, varscan2
- GREB1 | c.3654G>A p.S1218= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs370883365; called by muse, mutect2
- GSTCD | c.903C>A p.I301= (on ENST00000360505 / NM_001031720.3; = p.I214= on NM_024751.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64735081; called by muse, mutect2, varscan2
- HDLBP | c.1338C>T p.F446= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV60499653; called by muse, mutect2, varscan2
- HECW1 | c.249C>A p.V83= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV67833430; called by muse, mutect2, varscan2
- HELZ2 | c.3390C>T p.R1130= (on ENST00000467148 / NM_001037335.2; = p.R561= on NM_033405.3) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1348271309, COSV64410312; called by muse, mutect2
- HTR3B | c.945C>G p.L315= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV52746886; called by muse, mutect2
- ICE1 | c.3126A>G p.P1042= | Silent (SNP) | VAF 96/356 reads (27%) | catalogued as COSV56830220; called by muse, mutect2, varscan2
- IGHM | c.345C>A p.V115= | Silent (SNP) | VAF 31/53 reads (58%) | called by muse, mutect2, varscan2
- ITPR3 | c.2463G>T p.A821= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV65413613; called by muse, mutect2, varscan2
- KCNA5 | c.558G>A p.R186= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs778119687, COSV52907929; called by muse, mutect2, varscan2
- KCNK16 | c.84T>C p.G28= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV64678930; called by muse, mutect2, varscan2
- KIF15 | c.966C>T p.F322= | Silent (SNP) | VAF 117/236 reads (50%) | catalogued as rs539059165, COSV58163974; called by muse, mutect2, varscan2
- KIT | c.1680T>A p.V560= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV55415707, COSV55431522; called by muse, mutect2, varscan2
- LEPR | c.909G>T p.S303= | Silent (SNP) | VAF 62/133 reads (47%) | catalogued as COSV100756322, COSV60761364; called by muse, mutect2, varscan2
- LIN7A | c.555G>T p.V185= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV54025996; called by muse, mutect2, varscan2
- LRP2 | c.6849C>T p.I2283= | Silent (SNP) | VAF 105/209 reads (50%) | catalogued as rs1273204726, COSV55568177; called by muse, mutect2, varscan2
- LRRC57 | c.474C>G p.L158= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as COSV53000917, COSV53001557; called by muse, mutect2, varscan2
- LRRTM1 | c.1485C>T p.N495= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV54445296; called by muse, mutect2, varscan2
- LTF | c.897G>A p.K299= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV51610928; called by muse, mutect2, varscan2
- MARCHF6 | c.465T>C p.C155= | Silent (SNP) | VAF 46/444 reads (10%) | catalogued as COSV56885699; called by muse, mutect2
- MASP1 | c.285C>A p.T95= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as COSV51462746; called by muse, mutect2, varscan2
- MCM2 | c.1314C>T p.V438= | Silent (SNP) | VAF 72/478 reads (15%) | catalogued as COSV54036366; called by muse, mutect2, varscan2
- MUC5B | c.2925G>A p.A975= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs551502589, COSV71594609; ClinVar: likely benign; called by muse, mutect2, varscan2
- MVB12A | c.159C>T p.F53= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV57679556; called by muse, mutect2, varscan2
- MYH11 | c.1659G>C p.L553= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV55564901; called by muse, mutect2, varscan2
- NIPA1 | c.753G>A p.A251= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs199718530, COSV61680518; called by muse, mutect2, varscan2
- NLRP11 | c.513C>T p.I171= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV64088478; called by muse, mutect2, varscan2
- NOD1 | c.717C>T p.F239= | Silent (SNP) | VAF 53/175 reads (30%) | catalogued as COSV56114181; called by muse, mutect2, varscan2
- NOLC1 | c.1455A>G p.T485= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV64180959; called by muse, mutect2, varscan2
- NRCAM | c.2298G>A p.T766= (on ENST00000379028 / NM_001371124.1; = p.T750= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as rs759549444, COSV61045817; called by muse, mutect2, varscan2
- NUDT16L1 | c.489C>T p.N163= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs185620630, COSV99274078; called by muse, mutect2, varscan2
- OBSCN | c.7983C>T p.R2661= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs747910361, COSV52779958; called by muse, mutect2, varscan2
- OR4A47 | c.483T>C p.I161= | Silent (SNP) | VAF 58/237 reads (24%) | catalogued as rs758478022, COSV71445095; called by muse, mutect2, varscan2
- OR4C46 | c.654C>A p.V218= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs769201663, COSV60220779; called by muse, mutect2, varscan2
- OR8A1 | c.516C>G p.L172= | Silent (SNP) | VAF 49/226 reads (22%) | catalogued as COSV52509644, COSV52510618; called by muse, varscan2
- OR8A1 | c.612C>T p.F204= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV52509654; called by muse, varscan2
- OR8D4 | c.504C>T p.F168= | Silent (SNP) | VAF 164/510 reads (32%) | catalogued as COSV58431191; called by muse, varscan2
- OR8J3 | c.897T>C p.V299= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV56879338; called by muse, mutect2, varscan2
- OR9K2 | c.678C>T p.S226= (on ENST00000305377; = p.S204= on NM_001005243.1) | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV59533029; called by muse, mutect2, varscan2
- PAK5 | c.2022G>T p.R674= | Silent (SNP) | VAF 152/330 reads (46%) | catalogued as COSV62035020; called by muse, mutect2, varscan2
- PCDHB8 | c.687C>A p.V229= | Silent (SNP) | VAF 22/359 reads (6%) | catalogued as rs782144288, COSV50803383, COSV99176979; called by muse, mutect2
- PCDHGA4 | c.189C>A p.L63= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV54007607; called by muse, mutect2, varscan2
- PCNX3 | c.3534G>T p.A1178= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV63136943, COSV63139658; called by muse, mutect2
- PER3 | c.252C>G p.L84= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV50012848; called by muse, mutect2, varscan2
- PHLDB2 | c.1416C>T p.T472= | Silent (SNP) | VAF 96/451 reads (21%) | catalogued as rs112434778; called by muse, mutect2, varscan2
- PIK3R2 | c.2034C>G p.G678= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV55849723; called by muse, mutect2, varscan2
- PLBD2 | c.748C>T p.L250= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV55108516; called by muse, mutect2, varscan2
- PRSS21 | c.387C>T p.R129= | Silent (SNP) | VAF 93/266 reads (35%) | catalogued as COSV50052008; called by muse, mutect2, varscan2
- RTL5 | c.1674G>T p.G558= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV65454547; called by muse, mutect2, varscan2
- SCAF4 | c.594C>A p.G198= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV54585452, COSV54590992; called by muse, mutect2, varscan2
- SEC16A | c.5259C>T p.Y1753= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV51537351; called by muse, mutect2, varscan2
- SEMA3B | c.1710G>A p.S570= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs782650950, COSV57114982; called by muse, mutect2, varscan2
- SENP6 | c.1941C>T p.F647= | Silent (SNP) | VAF 192/313 reads (61%) | catalogued as COSV59193425; called by muse, mutect2, varscan2
- SIDT1 | c.1092C>T p.P364= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs201820793, COSV53505597; called by muse, mutect2, varscan2
- SIM1 | c.1737G>A p.E579= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as COSV53495372, COSV53496073; called by muse, varscan2
- SMG1 | c.9753T>C p.A3251= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1250039557, COSV67174088; called by muse, mutect2, varscan2
- SORCS1 | c.3129T>A p.A1043= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV53894459; called by muse, mutect2
- SOX3 | c.64C>A p.R22= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV65167929, COSV65168533; called by muse, mutect2, varscan2
- SPAG16 | c.1503C>A p.T501= | Silent (SNP) | VAF 38/215 reads (18%) | catalogued as COSV59094589; called by muse, mutect2, varscan2
- SPIC | c.147A>T p.G49= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV54692419; called by muse, mutect2, varscan2
- ST8SIA3 | c.27C>A p.V9= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV60654978; called by muse, mutect2, varscan2
- SUPT5H | c.801G>A p.V267= | Silent (SNP) | VAF 45/819 reads (5%) | catalogued as COSV63241458; called by muse, mutect2
- TDRD6 | c.3339G>T p.V1113= | Silent (SNP) | VAF 99/251 reads (39%) | catalogued as COSV60177689; called by muse, mutect2, varscan2
- TEX13B | c.333G>A p.L111= | Silent (SNP) | VAF 125/199 reads (63%) | catalogued as COSV57203698; called by muse, mutect2, varscan2
- TMEM268 | c.792C>T p.N264= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs554808792, COSV55987262; called by muse, mutect2, varscan2
- TSPY2 | c.70C>A p.R24= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV57837273; called by muse, mutect2, varscan2
- TTN | c.1251A>G p.K417= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV60265128; called by muse, mutect2, varscan2
- WNK1 | c.5715G>C p.V1905= (on ENST00000315939 / NM_018979.4; = p.V1657= on NM_014823.3) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV60042574; called by muse, mutect2, varscan2
- XK | c.147G>T p.A49= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV66120694; called by muse, mutect2, varscan2
- ZC3H7B | c.1911C>T p.F637= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs1341216763, COSV60964071; called by muse, mutect2, varscan2
- ZDBF2 | c.219T>A p.T73= | Silent (SNP) | VAF 75/136 reads (55%) | catalogued as COSV65629006; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1509T>C p.I503= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as COSV66023903; called by muse, mutect2, varscan2
- ZNF169 | c.111C>G p.T37= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV61765958; called by muse, mutect2, varscan2
- ZNF205 | c.852G>A p.E284= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54622499; called by muse, mutect2
- ZNF804B | c.939A>C p.T313= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV60846954; called by muse, mutect2, varscan2
- ZYG11B | c.1821C>T p.A607= | Silent (SNP) | VAF 28/210 reads (13%) | catalogued as COSV53755877; called by muse, mutect2, varscan2
- AC005863.1 | n.239A>G | RNA (SNP) | VAF 61/130 reads (47%) | called by muse, mutect2, varscan2
- ANK2 | c.84+57117G>T | Intron (SNP) | VAF 16/84 reads (19%) | catalogued as COSV52180938; called by muse, mutect2, varscan2
- DBI | c.9+555G>T | Intron (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100275855; called by muse, mutect2, varscan2
- IGKV1-13 | n.71A>G | RNA (SNP) | VAF 30/151 reads (20%) | catalogued as rs754027263; called by muse, mutect2, varscan2
- MBOAT1 | c.-2G>A | 5'UTR (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100208728; called by muse, mutect2, varscan2
- MIR892A | n.40C>A | RNA (SNP) | VAF 101/161 reads (63%) | called by muse, mutect2, varscan2
- NCOA7 | c.2245-1559A>G | Intron (SNP) | VAF 116/196 reads (59%) | called by muse, mutect2, varscan2
- SNORD115-20 | n.26G>T | RNA (SNP) | VAF 72/430 reads (17%) | catalogued as rs1284577592; called by muse, mutect2, varscan2
- SPATA8 | n.286C>A | RNA (SNP) | VAF 26/89 reads (29%) | catalogued as COSV60705403; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3362A>G | Intron (SNP) | VAF 186/322 reads (58%) | catalogued as COSV100314110; called by muse, mutect2, varscan2
- UBTFL2 | n.139G>A | RNA (SNP) | VAF 235/404 reads (58%) | called by muse, mutect2, varscan2
